Somatic mutation profile of tumor specimen 0E1HF3 from CCDI case PBCWDB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male.
Specimen 0E1HF3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a572655f-94c9-482d-b22a-bec10c56c984.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E1HFZ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f8fe095c-695c-4307-95d7-925917b5b3e7

The open-access MAF lists 13 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, 3'UTR 1, Frame Shift Ins 1, In Frame Del 1, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.2459A>G p.D820G | Missense Mutation (SNP) | VAF 242/374 reads (65%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913682, COSV55387023, COSV55391660, COSV55405326; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 107/326 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- HNRNPM | c.669_671del p.F224del | In Frame Del (DEL) | VAF 78/253 reads (31%) | called by mutect2, varscan2
- LCT | c.4015T>C p.F1339L | Missense Mutation (SNP) | VAF 98/289 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PABPC1 | c.1750A>C p.M584L | Missense Mutation (SNP) | VAF 114/386 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- POLE | c.4972G>T p.G1658W | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PQBP1 | c.200A>G p.N67S | Missense Mutation (SNP) | VAF 115/186 reads (62%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SEH1L | c.1007dup p.N336Kfs*30 | Frame Shift Ins (INS) | VAF 90/226 reads (40%) | called by mutect2, varscan2
- VPS13B | c.11977T>C p.Y3993H | Missense Mutation (SNP) | VAF 126/362 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ZNF510 | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 28/519 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2
- RTF2 | c.99A>G p.Q33= | Silent (SNP) | VAF 130/382 reads (34%) | catalogued as rs140775705; called by muse, mutect2, varscan2
- LZTR1 | c.2220-41C>T | Intron (SNP) | VAF 12/29 reads (41%) | catalogued as rs1166598109, COSV53147561; called by mutect2, varscan2
- PPM1E | c.*53del | 3'UTR (DEL) | VAF 26/82 reads (32%) | called by mutect2, varscan2
